Somatic mutation profile of tumor specimen ALCH-B3L4-TTP1-A (aliquot ALCH-B3L4-TTP1-A-3-0-D-A78R-36) from ALCHEMIST case ALCH-B3L4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.9 years (19,315 days).
Specimen ALCH-B3L4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4025f9f-6811-4a6e-900b-76f495811d9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3L4-NB1-A (Blood Derived Normal), aliquot ALCH-B3L4-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19661414-2cca-4dda-bae6-b2d056df70c6

The open-access MAF lists 570 somatic variants for this specimen: 388 protein-altering or splice-affecting, 110 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 110, Intron 38, Nonsense Mutation 33, 5'UTR 12, Frame Shift Del 9, 5'Flank 8, RNA 6, Splice Site 5, 3'UTR 5, Splice Region 5, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs397517065, COSV51762486; ClinVar: likely pathogenic; called by muse, varscan2
- DCX | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587783534, CM087661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD3B2 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs148200568, CM081308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 45/183 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 22/92 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ABCA8 | c.3777G>C p.K1259N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99285843; called by muse, mutect2, varscan2
- ABHD17A | c.410G>T p.R137L (on ENST00000292577 / NM_001130111.2; = p.R188L on NM_031213.4) | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV51751523; called by muse, mutect2, varscan2
- ACTRT1 | c.349del p.E117Kfs*6 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as COSV64419395; called by mutect2, pindel, varscan2
- ACTRT1 | c.239C>G p.T80R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV64420140; called by muse, mutect2, varscan2
- ADRB3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs202130418; called by muse, mutect2
- AFF4 | c.2918C>T p.T973M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769872229; called by muse, varscan2
- AGBL3 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99310877; called by muse, mutect2, varscan2
- ALX1 | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57492723; called by muse, mutect2, varscan2
- AMDHD1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141656136, COSV99900521; called by muse, varscan2
- ANKRD30B | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs754900800; called by muse, mutect2
- ANPEP | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs566665242; called by muse, mutect2, varscan2
- ANTXRL | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs529342540; called by muse, mutect2, varscan2
- APOB | c.11728G>A p.E3910K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as COSV51941351, COSV51948203; called by muse, mutect2, varscan2
- ASAH2 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781281745; called by muse, varscan2
- ATMIN | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55146078; called by muse, mutect2, varscan2
- ATR | c.2642A>T p.K881I | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV63390160; called by muse, varscan2
- BEND6 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV66070576; called by muse, mutect2, varscan2
- CAMKMT | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV101034671; called by muse, varscan2
- CARMIL3 | c.3048C>G p.F1016L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100549010, COSV57728263; called by muse, mutect2, varscan2
- CCDC116 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762878922; called by muse, mutect2, varscan2
- CCDC50 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 26/165 reads (16%) | catalogued as COSV66669685; called by muse, mutect2, varscan2
- CCR6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV100551074; called by muse, mutect2, varscan2
- CENPU | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as rs1183750274; called by muse, mutect2, varscan2
- CEP41 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV56220853; called by muse, mutect2, varscan2
- CFDP1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1452924605; called by muse, mutect2, varscan2
- CHD1 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339325; called by mutect2, varscan2
- CHIA | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV58474881, COSV58477113; called by muse, mutect2, varscan2
- CLCF1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV56862380; called by muse, mutect2, varscan2
- COL13A1 | c.644A>G p.E215G (on ENST00000398978 / NM_001130103.2; = p.E177G on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.331); catalogued as rs764803729; called by muse, mutect2, varscan2
- COL1A2 | c.3553G>T p.G1185* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV104397491; called by muse, mutect2, varscan2
- COL4A4 | c.1889C>G p.P630R | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as CD095037; called by muse, mutect2, varscan2
- COL4A4 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 32/157 reads (20%) | catalogued as COSV61636558; called by muse, mutect2, varscan2
- CSNK1G3 | c.709C>G p.H237D | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62054871; called by muse, mutect2, varscan2
- CTNNA2 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.633); catalogued as COSV58174997; called by muse, mutect2, varscan2
- CYP4V2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66505901; called by muse, mutect2, varscan2
- DCAF11 | c.849-3C>G | Splice Region (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100386884; called by muse, mutect2, varscan2
- DDR1 | c.2340C>G p.I780M (on ENST00000324771; = p.I743M on NM_001954.4) | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460947128, COSV61320541; called by muse, mutect2, varscan2
- DNAH6 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs529015397; called by muse, mutect2, varscan2
- DOCK9 | c.3305C>G p.S1102* (on ENST00000376460 / NM_001366676.2; = p.S1103* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV59646367; called by muse, mutect2, varscan2
- DOLK | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58281236; called by muse, mutect2, varscan2
- DPM1 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65373331; called by muse, mutect2, varscan2
- DYNC2I1 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV68104946; called by muse, mutect2, varscan2
- EAPP | c.470+1del p.X157_splice | Splice Site (DEL) | VAF 25/121 reads (21%) | catalogued as rs762657631; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.1274T>C p.I425T | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746465802; called by muse, mutect2, varscan2
- ELOF1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1295156015, COSV52947563; called by muse, mutect2, varscan2
- ERBB3 | c.3652G>C p.E1218Q | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV99918016; called by muse, mutect2, varscan2
- ETNPPL | c.1318A>G p.M440V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1242339707; called by muse, varscan2
- FAM160B2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774368845, COSV57160297; called by muse, mutect2, varscan2
- FGD4 | c.1673G>C p.R558P | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56784147, COSV56787519; called by muse, mutect2, varscan2
- FIG4 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1060501400; ClinVar: uncertain significance; called by muse, varscan2
- FLACC1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147899975; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- FZD2 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV59529587; called by muse, mutect2, varscan2
- GLYR1 | c.210G>C p.M70I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58928400; called by muse, mutect2, varscan2
- GOLGA6L2 | c.444G>C p.R148S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.765); catalogued as rs564873981; called by muse, mutect2, varscan2
- GOLM1 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57416089; called by muse, mutect2, varscan2
- GP6 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951449463; called by muse, mutect2, varscan2
- GRIN3A | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1441900422, COSV100701759; called by muse, mutect2, varscan2
- HERC2 | c.6380G>C p.R2127T | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99873561; called by muse, mutect2, varscan2
- HPS6 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV54626308; called by muse, mutect2, varscan2
- ICE1 | c.3424G>T p.E1142* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV56826602; called by muse, mutect2, varscan2
- IGSF11 | c.898C>T p.H300Y (on ENST00000393775 / NM_001015887.3; = p.H299Y on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV61166683, COSV61179118; called by muse, mutect2, varscan2
- IQCC | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as rs1242592550; called by muse, varscan2
- ITSN2 | c.3152C>G p.S1051* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV61949861; called by muse, mutect2, varscan2
- KCNE3 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59551760; called by muse, mutect2, varscan2
- KCNH7 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV59797052; called by muse, mutect2, varscan2
- KCTD3 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV52066846; called by muse, mutect2
- KIZ | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV55688530; called by muse, mutect2
- KLHL31 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.288); catalogued as COSV63882051; called by muse, mutect2, varscan2
- KLKB1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs777274175; called by muse, mutect2, varscan2
- KMT2C | c.10960C>T p.Q3654* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100069245; called by muse, mutect2, varscan2
- KRTAP10-4 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782820585; called by muse, mutect2, varscan2
- KRTAP10-6 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 47/682 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs782668686, COSV59958399; called by muse, mutect2
- KY | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101414945, COSV71017247; called by muse, mutect2, varscan2
- LCT | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 38/170 reads (22%) | catalogued as rs781299390; called by muse, mutect2, varscan2
- LDLR | c.2308C>G p.Q770E | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as CM002356; called by muse, mutect2, varscan2
- LENG8 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs772477609; called by muse, mutect2, varscan2
- LRPPRC | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.12); catalogued as COSV53235731; called by muse, mutect2, varscan2
- LRRC30 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754594498, COSV67301974; called by muse, mutect2, varscan2
- LRRC43 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs201663367; called by muse, mutect2, varscan2
- MAGEL2 | c.1975G>T p.V659L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754093332; called by muse, mutect2
- MAP3K19 | c.1008G>C p.L336F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59641170; called by muse, mutect2, varscan2
- MAP6 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59078487; called by muse, mutect2
- MICA | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as rs753096505; called by muse, mutect2, varscan2
- MLH3 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs927878214; called by muse, mutect2, varscan2
- MROH5 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 63/449 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.23); catalogued as COSV71302957; called by muse, mutect2, varscan2
- MYO7A | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1457972113; called by muse, mutect2, varscan2
- NAPSA | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99515849; called by muse, mutect2, varscan2
- NECAB3 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as rs757580108, COSV99864911; called by muse, mutect2
- NOTCH4 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs1213984385; called by muse, mutect2, varscan2
- NPAP1 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as rs1461589456; called by muse, mutect2, varscan2
- NPAP1 | c.3122G>A p.G1041E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61505914, COSV61508433; called by muse, mutect2, varscan2
- NRXN1 | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV100455549; called by muse, varscan2
- NTRK3 | c.1640G>C p.G547A | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62298436; called by muse, mutect2, varscan2
- OPA3 | c.152G>A p.W51* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs747890876; called by muse, mutect2, varscan2
- OR10A2 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV56300041; called by muse, mutect2, varscan2
- OR14C36 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as COSV100507500; called by muse, mutect2, varscan2
- OR4K2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs267603912, COSV53850238; called by muse, mutect2, varscan2
- PCBP1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100340018, COSV57849597; called by muse, mutect2, varscan2
- PCDHB6 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1554278045, COSV50733989; called by muse, mutect2, varscan2
- PHC2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV57101995; called by muse, mutect2, varscan2
- PHYHD1 | c.553G>A p.G185S (on ENST00000372592 / NM_001100876.2; = p.T177= on NM_174933.4) | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs779787024; called by muse, mutect2, varscan2
- PIKFYVE | c.2001C>G p.I667M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs776524286, COSV100011188, COSV52245237; called by muse, mutect2, varscan2
- PITX1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs757554141, COSV104373325; called by muse, varscan2
- PNPO | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV56666104; called by muse, mutect2, varscan2
- PPP6R3 | c.2273C>T p.A758V (on ENST00000393800 / NM_001352375.2; = p.A678V on NM_018312.5) | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1321679775, COSV55723479; called by muse, mutect2, varscan2
- PRR19 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs138561589; called by muse, mutect2, varscan2
- PRSS16 | c.1477-1G>A p.X493_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as rs573409353; called by muse, mutect2, varscan2
- PSG9 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1282198339; called by muse, mutect2, varscan2
- PTPRB | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV54243277; called by muse, mutect2, varscan2
- PYGM | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51226221; called by muse, mutect2, varscan2
- RAP1GAP | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs763968945, COSV99265204; called by muse, mutect2, varscan2
- RELN | c.5144C>G p.S1715* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as COSV58986995; called by muse, mutect2, varscan2
- RFX7 | c.858G>C p.M286I (on ENST00000559447 / NM_001368074.1; = p.M383I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs779809085; called by muse, mutect2
- RIOK1 | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.083); catalogued as COSV53572393, COSV53573070; called by muse, mutect2, varscan2
- RSPRY1 | c.1472T>G p.F491C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs779133115; called by muse, varscan2
- RUFY4 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1196670504; called by muse, mutect2
- RYR2 | c.13240G>C p.E4414Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as rs1186955550; called by muse, varscan2
- SCN3A | c.5013C>G p.I1671M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51807232; called by muse, mutect2, varscan2
- SEMA3B | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs377434380; called by muse, mutect2, varscan2
- SEMA3E | c.249G>T p.L83F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57104226; called by muse, mutect2, varscan2
- SERPINH1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs535510332, COSV63998178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK2 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 52/943 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99573481; called by muse, mutect2
- SHROOM3 | c.4216G>A p.D1406N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs200718300, COSV56035556; called by muse, mutect2, varscan2
- SIGLEC6 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1237553594, COSV58431698; called by muse, varscan2
- SIGLEC6 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV58434367; called by muse, varscan2
- SIRPG | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53809007; called by muse, mutect2, varscan2
- SKOR2 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.737); catalogued as rs1369715370; called by muse, mutect2, varscan2
- SLC2A10 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs776700297, COSV63716030; called by muse, mutect2, varscan2
- SLC30A1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99056039; called by muse, mutect2, varscan2
- SLC39A13 | c.979G>A p.G327S (on ENST00000362021 / NM_001128225.3; = p.G320S on NM_152264.4) | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214072258, COSV54082193; called by muse, mutect2, varscan2
- SLC5A12 | c.458-2A>G p.X153_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as rs1465277508, COSV99744359; called by muse, mutect2, varscan2
- SLC6A7 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 23/211 reads (11%) | catalogued as rs1562078193; called by muse, mutect2, varscan2
- SLCO1C1 | c.1966C>A p.L656I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as COSV99858946; called by muse, mutect2, varscan2
- SMOC1 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62760967; called by muse, varscan2
- SPATA16 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100650782, COSV63531143; called by muse, mutect2, varscan2
- SPATA31D1 | c.3569C>G p.S1190* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61201934; called by muse, mutect2, varscan2
- SPTB | c.6917C>T p.S2306F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1444221072, COSV55979738; called by muse, mutect2, varscan2
- SYDE1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs552062430; called by muse, varscan2
- TBX18 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as rs753798713; called by muse, mutect2, varscan2
- TMEM191B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1248195442; called by muse, mutect2, varscan2
- TMEM221 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1187589945; called by muse, mutect2, varscan2
- TNN | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs756217445; called by muse, mutect2, varscan2
- TRIM24 | c.1858A>T p.N620Y (on ENST00000343526 / NM_015905.3; = p.N586Y on NM_003852.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV58972969; called by muse, mutect2
- TSPYL6 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV57817908; called by muse, mutect2, varscan2
- TTN | c.73789G>T p.A24597S (on ENST00000591111; = p.A17173S on NM_003319.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | PolyPhen possibly damaging (0.475); catalogued as COSV100613005; called by muse, mutect2, varscan2
- TTN | c.47212G>C p.E15738Q (on ENST00000591111; = p.E8314Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | PolyPhen possibly damaging (0.836); catalogued as rs770795675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH3 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51861011; called by muse, mutect2, varscan2
- UBQLN3 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as rs1170952416; called by muse, mutect2, varscan2
- WAPL | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV53937435; called by muse, mutect2, varscan2
- XPOT | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1353750401; called by muse, mutect2, varscan2
- ZFHX4 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.277); catalogued as rs751284629; called by muse, mutect2, varscan2
- ZNF100 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99973856, COSV99974176; called by muse, mutect2, varscan2
- ZNF569 | c.-41C>G | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as rs757520077; called by muse, mutect2
- ZNF665 | c.508A>G p.K170E (on ENST00000600412; = p.K235E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1159531406; called by muse, mutect2, varscan2
- ZNF679 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV55381714; called by muse, mutect2, varscan2
- ZNF75D | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV66132903; called by muse, mutect2, varscan2
- ZNF85 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100060132; called by muse, varscan2
- ZSWIM8 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as rs530541959, COSV67132518; called by muse, mutect2, varscan2
- A1CF | c.1541C>A p.A514E (on ENST00000373993 / NM_138932.2; = p.A506E on NM_014576.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, varscan2
- ADAM21 | c.407del p.L136* | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, varscan2
- ADAM9 | c.1185A>T p.L395F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRL4 | c.1910A>T p.H637L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, varscan2
- ADO | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AKAP3 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKAP4 | c.1524G>C p.W508C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD36C | c.3087G>T p.W1029C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, varscan2
- ARAP3 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARID1A | c.3130G>A p.V1044M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- B3GNT7 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEND2 | c.1555del p.L519* | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by pindel, varscan2
- BIRC6 | c.10166C>G p.S3389C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- BMP8A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf185 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- C2CD3 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, varscan2
- C2orf16 | c.2595G>C p.K865N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CALCA | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCNT1 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CD163 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CDC73 | c.1317-1G>T p.X439_splice | Splice Site (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.1345G>A p.E449K (on ENST00000357886 / NM_001365728.1; = p.E435K on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP170 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CHD3 | c.4347G>C p.E1449D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2
- CHML | c.1538C>A p.S513* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- CLDN15 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- COLEC11 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPEB4 | c.929del p.G310Efs*12 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- CUX2 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CYYR1 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DAGLA | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DAZL | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DCAF11 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DLEC1 | c.2649C>G p.I883M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DMD | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DNAH5 | c.13650G>A p.M4550I | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.11132A>G p.N3711S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- DNAH7 | c.6169C>G p.Q2057E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNM1L | c.2143G>C p.D715H (on ENST00000549701 / NM_012062.5; = p.D678H on NM_005690.4) | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DUOX2 | c.2991G>C p.K997N | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EBF1 | c.555-8C>G | Splice Region (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- EFHB | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- EGFL6 | c.36_38del p.L13del | In Frame Del (DEL) | VAF 34/78 reads (44%) | called by pindel, varscan2
- EIF3L | c.374-3C>T | Splice Region (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- ERBB3 | c.3856G>C p.E1286Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ETS1 | c.1042A>C p.K348Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- EZH1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- FAT1 | c.5281A>T p.N1761Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.8281G>T p.A2761S | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FCGBP | c.5324C>A p.T1775N | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.754); called by mutect2, varscan2
- FPR1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- FRY | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FSD1 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- FTCDNL1 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FXR1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GALNT6 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCFC2 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | called by muse, varscan2
- GDF1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPATCH1 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR149 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPR31 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- GRHL2 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, varscan2
- GRIN3A | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GUCY2C | c.2070G>C p.E690D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- H3C11 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- HECW2 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELZ2 | c.2481G>C p.Q827H (on ENST00000467148 / NM_001037335.2; = p.Q258H on NM_033405.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HIBADH | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIP1R | c.1825_1827dup p.E609dup | In Frame Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- HLA-F | c.605_608del p.R202Qfs*20 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel
- HPS5 | c.1244C>G p.S415C (on ENST00000349215 / NM_181507.2; = p.S301C on NM_007216.4) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- IGHV1-3 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGSF1 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IQCC | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- KCNMB4 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KDM3B | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- KIAA1958 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF25 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KIF6 | c.611T>A p.L204* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- KIFC2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KIT | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- KIZ | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KLHL14 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KRTAP19-5 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 59/276 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LDHB | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- LEO1 | c.1419A>G p.I473M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LIMA1 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LINGO1 | c.1082T>A p.L361Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMBR1L | c.1239G>A p.L413= | Splice Region (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- LNX1 | c.583A>G p.I195V (on ENST00000263925 / NM_001126328.3; = p.I99V on NM_032622.2) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRIQ3 | c.1360A>G p.R454G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, varscan2
- MAGI3 | c.1767del p.F590Lfs*12 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- MAP4 | c.3056G>C p.G1019A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF4 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2
- MED29 | c.450G>C p.Q150H (on ENST00000615911; = p.Q129H on NM_017592.4) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- METTL23 | c.356dup p.L119Ffs*17 | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- MKI67 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MORC3 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MORC4 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYB | c.1546C>G p.Q516E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, varscan2
- MYCBP2 | c.2541T>G p.I847M (on ENST00000357337; = p.I885M on NM_015057.5) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYH11 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYH14 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 47/345 reads (14%) | called by muse, mutect2, varscan2
- MYH14 | c.1255C>A p.R419S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NCOA6 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- NEK11 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- NFASC | c.1750G>C p.E584Q (on ENST00000339876 / NM_001378329.1; = p.E595Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NIPBL | c.6002G>A p.R2001K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NLRP9 | c.1682T>C p.V561A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NOTCH3 | c.5144G>C p.G1715A | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NR1I2 | c.983A>T p.Y328F | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NXPH2 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- OGT | c.2368A>T p.I790F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- OPA1 | c.1723G>A p.E575K (on ENST00000361510 / NM_130837.3; = p.E520K on NM_015560.3) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OR1A1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR2A14 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T10 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OR4A15 | c.573T>A p.Y191* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- OR4Q2 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52A1 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OSBPL8 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- OVCH1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PAICS | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PARD3B | c.1597A>T p.I533F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PARP14 | c.3011A>G p.E1004G | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARVA | c.158del p.G53Efs*2 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- PCLO | c.11332G>T p.A3778S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCNT | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PGLYRP3 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PHF3 | c.3061A>G p.K1021E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, varscan2
- PHKA1 | c.2134C>G p.Q712E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PIP4P2 | c.244A>G p.N82D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PIP5K1B | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- PITX1 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, varscan2
- PKHD1 | c.1055G>T p.W352L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PKN1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PLEKHA5 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); called by muse, mutect2
- PLPPR2 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2
- PLXNA4 | c.5406G>T p.K1802N | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXND1 | c.5089A>G p.K1697E | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POGLUT3 | c.1032C>G p.F344L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, varscan2
- POLQ | c.2028G>C p.L676F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POTEB3 | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); called by mutect2, varscan2
- POTEI | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 129/527 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PPP6R3 | c.1878_1886delinsT p.K626Nfs*18 (on ENST00000393800 / NM_001352375.2; = p.K546Nfs*18 on NM_018312.5) | Frame Shift Del (DEL) | VAF 33/55 reads (60%) | called by pindel, varscan2*
- PRAG1 | c.4086G>A p.M1362I | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PRDM9 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSIP1 | c.617C>G p.S206* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- PTBP2 | c.979G>T p.A327S (on ENST00000426398 / NM_001300986.2; = p.A319S on NM_021190.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTGER4 | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTK2 | c.1600C>G p.L534V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- RABGAP1 | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, varscan2
- RAD17 | c.469C>G p.Q157E (on ENST00000380774 / NM_133339.2; = p.Q146E on NM_002873.1) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAI14 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RANBP6 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RBM48 | c.703A>T p.M235L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- RC3H1 | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- RELN | c.6315C>G p.F2105L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RFX6 | c.1738A>G p.K580E | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RGPD3 | c.3070G>C p.D1024H | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RMI1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | called by muse, varscan2
- RNF133 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RPL22L1 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS6KA1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- RYR1 | c.13282G>C p.E4428Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); called by mutect2, varscan2
- RYR2 | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- SALL3 | c.1669T>C p.S557P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMHD1 | c.1496T>C p.I499T | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SBF2 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SCIN | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SELL | c.464G>T p.W155L (on ENST00000650983; = p.W142L on NM_000655.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGPP2 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SHLD2 | c.1348T>A p.S450T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SIX3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SLC16A11 | c.727_729dup p.A243dup (on ENST00000308009; = p.A219dup on NM_153357.3) | In Frame Ins (INS) | VAF 23/118 reads (19%) | called by mutect2, pindel, varscan2
- SLC45A4 | c.2032G>A p.V678M (on ENST00000517878 / NM_001286646.2; = p.V627M on NM_001080431.2) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC5A12 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, varscan2
- SLCO1B1 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SLITRK5 | c.1603C>A p.L535M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- SPEF2 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STK16 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SYDE2 | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, varscan2
- SYT6 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SYVN1 | c.1582C>A p.L528M (on ENST00000377190 / NM_172230.3; = p.L527M on NM_032431.3) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SYVN1 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TACC3 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TAF15 | c.613G>T p.D205Y (on ENST00000605844 / NM_139215.3; = p.D202Y on NM_003487.4) | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEAD1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TKTL2 | c.559C>A p.R187S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM67 | c.2557-2A>T p.X853_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- TRANK1 | c.3592C>G p.L1198V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- TRANK1 | c.2458C>T p.Q820* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- TRAV13-1 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.3); called by muse, mutect2
- TRIO | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, varscan2
- TRIO | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TRMU | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); called by muse, mutect2
- TRRAP | c.6730G>A p.A2244T (on ENST00000359863 / NM_001244580.1; = p.A2226T on NM_003496.3) | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TSPYL6 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTC7A | c.1777A>T p.I593F | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- UNC13A | c.2953G>C p.E985Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- UNC13C | c.6545T>A p.L2182* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- USH2A | c.10502G>A p.G3501E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- USP33 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP33 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- VN1R2 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR87 | c.2020A>G p.M674V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- XRCC5 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB41 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.6353G>T p.G2118V | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP28 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ZFP57 | c.365_368del p.K122Sfs*9 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- ZIC1 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF136 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, varscan2
- ZNF25 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- ZNF28 | c.536G>T p.R179I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by mutect2, varscan2
- ZNF385B | c.582T>A p.S194R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF564 | c.1458C>G p.F486L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF600 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF708 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AC068580.4 | c.1500C>T p.F500= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV100415298; called by muse, mutect2, varscan2
- ACVR2A | c.471A>C p.A157= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- ADCY8 | c.2712G>A p.L904= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- AFF3 | c.1083G>T p.S361= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57869139; called by muse, mutect2, varscan2
- ALMS1 | c.6297G>A p.E2099= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100042542; called by muse, mutect2
- AMBP | c.24C>T p.L8= | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- ANKRD17 | c.1476C>T p.S492= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV58224191; called by muse, mutect2, varscan2
- ARAF | c.1143C>T p.I381= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs906768787, COSV51693224; called by muse, mutect2, varscan2
- ARMC8 | c.171C>T p.L57= (on ENST00000469044 / NM_001363941.2; = p.L43= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
- ATP10B | c.741C>G p.L247= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3009C>T p.N1003= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ATXN7 | c.657C>A p.S219= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- C3orf80 | c.355C>A p.R119= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- CAPN14 | c.732G>A p.K244= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2
- CATIP | c.966C>G p.P322= | Silent (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- CD22 | c.1308C>T p.D436= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs1226823063; called by muse, mutect2, varscan2
- CDH12 | c.1050T>C p.A350= | Silent (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- CHD4 | c.2506C>T p.L836= (on ENST00000357008 / NM_001363606.2; = p.L849= on NM_001273.5) | Silent (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- COL6A5 | c.258C>T p.T86= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- CPLX4 | c.319C>A p.R107= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- CRIM1 | c.84G>T p.A28= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, varscan2
- CYFIP1 | c.2379C>T p.T793= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- DCST1 | c.426C>T p.N142= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs766285350; called by muse, mutect2, varscan2
- DNAH5 | c.7683T>C p.S2561= | Silent (SNP) | VAF 43/208 reads (21%) | called by muse, mutect2, varscan2
- DOCK11 | c.3360G>A p.L1120= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52242170; called by muse, mutect2, varscan2
- DSCAM | c.1638C>T p.F546= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- ECI1 | c.273C>T p.F91= | Silent (SNP) | VAF 50/206 reads (24%) | called by muse, mutect2, varscan2
- EFCAB9 | c.249G>A p.K83= | Silent (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- EIF5B | c.9G>A p.K3= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- ENG | c.1785C>T p.I595= | Silent (SNP) | VAF 67/248 reads (27%) | called by muse, mutect2, varscan2
- ERAP2 | c.1929C>G p.L643= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- EYS | c.2721T>C p.D907= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1470444230, COSV65488795; called by muse, mutect2, varscan2
- F13A1 | c.1242G>T p.S414= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV99343955; called by muse, mutect2, varscan2
- FAP | c.702T>C p.I234= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs199680554; called by muse, mutect2, varscan2
- FBXO24 | c.186C>A p.L62= (on ENST00000241071 / NM_033506.3; = p.L100= on NM_012172.5) | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- FLT3 | c.576G>A p.P192= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1170660721, COSV54056537; called by muse, mutect2, varscan2
- FOXB2 | c.1029C>A p.A343= | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- G6PC | c.1035C>T p.L345= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs750975981; called by muse, mutect2, varscan2
- GLRA1 | c.570G>A p.T190= | Silent (SNP) | VAF 68/118 reads (58%) | catalogued as rs768174352, COSV51013087; called by muse, mutect2, varscan2
- GOLGA6L2 | c.2109G>A p.R703= | Silent (SNP) | VAF 75/581 reads (13%) | called by muse, varscan2
- GPD2 | c.135C>T p.C45= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- GPRIN2 | c.1092A>T p.P364= | Silent (SNP) | VAF 31/201 reads (15%) | called by muse, mutect2, varscan2
- GRSF1 | c.24C>A p.L8= | Silent (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- GTF3C1 | c.1788G>A p.L596= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs745400564; called by muse, mutect2, varscan2
- IFNGR2 | c.771G>A p.S257= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as rs115458101; called by muse, varscan2
- IGSF1 | c.729C>T p.S243= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- INTS3 | c.2925A>G p.E975= | Silent (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- IQCC | c.426G>A p.R142= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1182226293; called by muse, mutect2, varscan2
- KCNC3 | c.1707G>T p.P569= | Silent (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- KCNMB2 | c.477G>A p.V159= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- KIF21B | c.4707C>T p.I1569= (on ENST00000422435 / NM_001252100.2; = p.I1556= on NM_017596.4) | Silent (SNP) | VAF 84/293 reads (29%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.342G>A p.V114= | Silent (SNP) | VAF 91/231 reads (39%) | catalogued as COSV54395512; called by muse, mutect2
- LRIG1 | c.2541G>A p.G847= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs1471797675; called by muse, mutect2, varscan2
- MAP3K6 | c.261G>A p.P87= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1445382903; called by muse, varscan2
- MAPK4 | c.78G>A p.L26= | Silent (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- MCTP2 | c.2514C>T p.I838= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs151286458, COSV63294886; called by muse, mutect2, varscan2
- MEGF10 | c.3036G>A p.K1012= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57247227; called by muse, mutect2, varscan2
- MIGA2 | c.1365C>T p.V455= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- MIGA2 | c.1506G>A p.V502= | Silent (SNP) | VAF 35/122 reads (29%) | called by muse, varscan2
- MIGA2 | c.1560C>G p.V520= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99477517; called by muse, varscan2
- MPEG1 | c.1053A>C p.T351= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- MRGPRE | c.625C>A p.R209= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs547469383; called by muse, mutect2, varscan2
- MROH2B | c.4692G>A p.Q1564= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1212700383; called by muse, mutect2, varscan2
- MTSS1 | c.1141C>A p.R381= | Silent (SNP) | VAF 89/437 reads (20%) | called by muse, varscan2
- MUC2 | c.429C>A p.L143= | Silent (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- NDC80 | c.381G>A p.K127= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV55247302; called by muse, varscan2
- NDN | c.87G>A p.S29= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1429214688, COSV59360227, COSV59360958; called by muse, mutect2, varscan2
- NEGR1 | c.66C>A p.L22= | Silent (SNP) | VAF 43/222 reads (19%) | called by muse, mutect2, varscan2
- NEURL2 | c.345C>T p.I115= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- NF1 | c.2289G>A p.L763= | Silent (SNP) | VAF 39/151 reads (26%) | called by muse, mutect2, varscan2
- NKD2 | c.930G>A p.S310= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs147626744; called by muse, mutect2, varscan2
- NLGN4X | c.1266C>T p.F422= | Silent (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- OPN1MW | c.939T>C p.S313= | Silent (SNP) | VAF 31/59 reads (53%) | called by mutect2, varscan2
- OR4C13 | c.483C>T p.I161= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV101634178, COSV73648704; called by muse, mutect2, varscan2
- OR4C5 | c.817C>A p.R273= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs77053100; called by muse, mutect2, varscan2
- PCDHAC2 | c.924C>T p.F308= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs782694266; called by muse, mutect2, varscan2
- POMGNT1 | c.555C>T p.L185= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as COSV100915517; called by muse, mutect2, varscan2
- PROX1 | c.1572G>A p.L524= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- PRSS57 | c.162G>A p.G54= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- PTBP1 | c.1488C>A p.I496= (on ENST00000349038 / NM_031991.4; = p.I522= on NM_002819.5) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV62461846; called by muse, mutect2, varscan2
- PTBP1 | c.1578C>T p.F526= (on ENST00000349038 / NM_031991.4; = p.F552= on NM_002819.5) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1225227137, COSV62461149; called by muse, mutect2, varscan2
- RANBP2 | c.8031C>T p.F2677= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs143766371; called by muse, mutect2, varscan2
- REST | c.3207C>T p.F1069= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV58362542; called by muse, mutect2, varscan2
- RFK | c.246C>T p.I82= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs749657889, COSV65060917; called by muse, mutect2, varscan2
- RGPD3 | c.2076A>T p.A692= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- RTN1 | c.1654C>A p.R552= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as COSV50720798; called by muse, mutect2, varscan2
- RWDD1 | c.210C>T p.F70= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1215121955; called by muse, mutect2, varscan2
- RYR3 | c.771G>T p.G257= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- S1PR1 | c.852G>A p.V284= | Silent (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- S1PR2 | c.528C>T p.L176= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs770771070, COSV100495285; called by muse, mutect2, varscan2
- SALL2 | c.2094G>A p.K698= | Silent (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- SEPTIN12 | c.540G>A p.L180= | Silent (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.139C>A p.R47= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs1285373121, COSV59479507; called by muse, mutect2, varscan2
- SLC7A1 | c.567C>T p.V189= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV66331985; called by muse, mutect2, varscan2
- SPATA31D1 | c.699C>T p.F233= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as COSV61201248; called by muse, mutect2, varscan2
- SYNPO | c.2475C>G p.A825= (on ENST00000394243 / NM_001166208.2; = p.A581= on NM_007286.6) | Silent (SNP) | VAF 78/393 reads (20%) | called by muse, mutect2, varscan2
- TACC2 | c.6060C>T p.F2020= (on ENST00000334433; = p.F98= on NM_006997.4) | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as rs1389808854; called by muse, mutect2, varscan2
- TEX14 | c.1668C>T p.D556= (on ENST00000240361 / NM_001201457.2; = p.D550= on NM_031272.5) | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- TLCD4 | c.129C>T p.F43= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- TMEM132C | c.495G>A p.E165= | Silent (SNP) | VAF 64/275 reads (23%) | called by muse, mutect2, varscan2
- TRANK1 | c.2682C>T p.I894= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1107G>A p.Q369= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53671795; called by muse, mutect2, varscan2
- TUBA4A | c.1065C>T p.I355= | Silent (SNP) | VAF 43/213 reads (20%) | called by muse, mutect2, varscan2
- TUT1 | c.1638C>T p.D546= | Silent (SNP) | VAF 52/86 reads (60%) | called by muse, mutect2, varscan2
- USH2A | c.3120C>T p.S1040= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- VARS1 | c.753G>A p.Q251= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as rs778535534; called by muse, varscan2
- WDR97 | c.2916G>A p.L972= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- ZBTB25 | c.294G>A p.G98= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- ZNF519 | c.1170C>T p.Y390= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs542240439, COSV73913366; called by muse, mutect2, varscan2
- ZNF610 | c.585A>T p.A195= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- AC005670.2 | chr17:47049917 C>T | 3'Flank (SNP) | VAF 26/573 reads (5%) | catalogued as rs776148582; called by muse, mutect2
- AC133561.1 | n.1371G>T | RNA (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- ACADS | c.-26G>T | 5'UTR (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1810-737G>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- AKAP14 | c.261+34C>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs781424594, COSV57629389; called by muse, mutect2, varscan2
- ANK2 | c.4372-30C>G | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179779G>C | Intron (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- ATXN10 | c.-46C>G | 5'UTR (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99426346; called by muse, mutect2, varscan2
- AZIN1 | chr8:102864339 C>T | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- BANK1 | c.-46G>T | 5'UTR (SNP) | VAF 57/187 reads (30%) | catalogued as rs367959578; called by muse, mutect2, varscan2
- BCORL1 | c.4306-2886G>C | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- BMS1P1 | n.803C>T | RNA (SNP) | VAF 34/186 reads (18%) | catalogued as rs1185363942; called by muse, varscan2
- C1S | c.1067-20C>T | Intron (SNP) | VAF 64/216 reads (30%) | called by muse, mutect2, varscan2
- C6orf223 | n.334G>A | RNA (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- CACTIN | c.643-58G>A | Intron (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- CD3D | c.56-289C>G | Intron (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- CD99L2 | c.-44C>T | 5'UTR (SNP) | VAF 8/23 reads (35%) | catalogued as rs1198197080; called by muse, mutect2
- CEP41 | c.*927T>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by mutect2, varscan2
- CEP41 | c.-8G>C | 5'UTR (SNP) | VAF 70/352 reads (20%) | called by muse, mutect2
- CPLANE1 | c.*5494C>T | 3'UTR (SNP) | VAF 15/102 reads (15%) | catalogued as rs578127199, COSV57059861; called by muse, mutect2, varscan2
- CRIP2 | c.406+17del | Intron (DEL) | VAF 16/79 reads (20%) | catalogued as rs1555436681; called by mutect2, pindel, varscan2
- CSMD1 | c.6245-10310G>T | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- CSTF3 | c.28-2895G>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs763179783; called by muse, mutect2, varscan2
- CTNND2 | c.3343+1379C>G | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- CXCL12 | c.266+290T>C | Intron (SNP) | VAF 6/37 reads (16%) | called by muse, varscan2
- D2HGDH | c.1141-753G>C | Intron (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- DAPK2 | c.659+31C>G | Intron (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2
- DNAH17 | c.2532+20G>T | Intron (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- DNAH17 | c.2532+19G>A | Intron (SNP) | VAF 53/225 reads (24%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.415C>G | RNA (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- ESRP1 | chr8:94639281 G>A | 5'Flank (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2770C>T | Intron (SNP) | VAF 9/41 reads (22%) | catalogued as rs746773734; called by muse, mutect2, varscan2
- HEG1 | c.1589-1018G>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+947C>T | Intron (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922324 G>A | 5'Flank (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.321C>A | RNA (SNP) | VAF 43/369 reads (12%) | called by muse, mutect2, varscan2
- INAVA | c.-27G>C | 5'UTR (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+12G>C | Intron (SNP) | VAF 45/270 reads (17%) | catalogued as rs781551364; called by muse, mutect2, varscan2
- KIF21B | c.-17C>T | 5'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1367G>C | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- LMNTD1 | c.*11C>G | 3'UTR (SNP) | VAF 11/68 reads (16%) | catalogued as rs768528995; called by muse, varscan2
- MEGF11 | c.2215+46G>T | Intron (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- MIR4771-1 | chr2:87193486 C>G | 5'Flank (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- NAGLU | chr17:42547383 G>T | 3'Flank (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- NDUFA9 | c.50-666C>G | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- NTRK3 | c.2133+12670G>C | Intron (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- NUBP2 | c.-32G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs778193041; called by muse, mutect2, varscan2
- OGFRL1 | c.-22C>A | 5'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2
- OR4C4P | n.93G>C | RNA (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4692del | Intron (DEL) | VAF 52/121 reads (43%) | called by mutect2, pindel, varscan2
- PCSK9 | c.524-1099C>T | Intron (SNP) | VAF 32/147 reads (22%) | called by mutect2, varscan2
- PDE4C | c.595+23C>A | Intron (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- PDGFA | chr7:520090 C>T | 5'Flank (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- PLEC | c.*27A>G | 3'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as rs1554668055; called by muse, mutect2, varscan2
- PSG8 | c.-15_-14del | 5'UTR (DEL) | VAF 20/116 reads (17%) | catalogued as rs772403302; called by pindel, varscan2
- PTBP2 | c.-11C>G | 5'UTR (SNP) | VAF 50/227 reads (22%) | catalogued as rs1356132749; called by muse, mutect2, varscan2
- RAD51B | c.1036+9459G>T | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, varscan2
- ROGDI | c.117+341G>A | Intron (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- SLC52A2 | chr8:144354312 G>T | 5'Flank (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- SLC52A2 | chr8:144354313 T>A | 5'Flank (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- TANC1 | c.495+40G>T | Intron (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- TGFA | c.476-866G>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99772793; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100249 C>T | 3'Flank (SNP) | VAF 44/156 reads (28%) | catalogued as rs761001758; called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>A | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as rs1290972874, COSV63509647; called by mutect2, varscan2
- TPTE2 | c.1395+653G>C | Intron (SNP) | VAF 11/74 reads (15%) | catalogued as rs768595923; called by muse, mutect2, varscan2
- VPS9D1 | c.176-1071G>T | Intron (SNP) | VAF 37/86 reads (43%) | catalogued as COSV57067113; called by muse, varscan2
- WT1 | chr11:32439314 G>T | 5'Flank (SNP) | VAF 19/59 reads (32%) | catalogued as rs1200051875; called by muse, mutect2, varscan2
- ZEB1 | c.-32G>A | 5'UTR (SNP) | VAF 23/213 reads (11%) | catalogued as rs1470666425; called by muse, mutect2, varscan2
- ZNF721 | c.-3+25050C>T | Intron (SNP) | VAF 37/117 reads (32%) | catalogued as COSV100167694; called by muse, mutect2, varscan2
- ZNF783 | c.*972+41G>T | Intron (SNP) | VAF 23/85 reads (27%) | catalogued as rs938120634; called by muse, mutect2, varscan2
- ZNF789 | c.152-1810C>A | Intron (SNP) | VAF 32/150 reads (21%) | catalogued as COSV58874568; called by muse, mutect2, varscan2
- ZRANB2 | c.771-757C>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
